CCDI case PBBWUN — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Gliomas; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/87e82c2c-6c45-4ccb-9f94-e0c0a7739c7e

Demographics
Sex at birth: female; Race: white; Vital status: Alive.

Diagnoses (1)
1. Glioma, malignant: ICD-O-3 morphology code: 9380/3; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 2.2 years (796 days).

Biospecimens (3 samples)
- Sample 0DJG5G: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DJG5H: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DJG5I: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
